Surgical pathology report (de-identified scan), TCGA case TCGA-WY-A85B, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Johns Hopkins, specimen TCGA-WY-A85B-01A (Primary Tumor).

[page 1 of 3]
Patient: [REDACTED]

Path# [REDACTED]

[REDACTED] # [REDACTED]

Accessioned

Birthdate: [REDACTED]

(Age

Loc: [REDACTED]

Gender: M

Spec. Taken

=====

INTERPRETATION AND DIAGNOSIS:

1-2. BRAIN TUMOR (RESECTION):

INFILTRATING ASTROCYTOMA, WHO GRADE II.

NOTE: An immunohistochemical stain for p53 is positive and a stain for Ki67 shows a low proliferation index. Dr. [REDACTED] has reviewed this case and agrees.

3. TEMPORAL LOBE, BRAIN (EXCISION):

NO TUMOR SEEN.

[REDACTED]

*Electronic signature

ADDENDUM:

GENETIC ANALYSIS SHOWED NO EVIDENCE OF LOH AT 1p. THERE IS NO DEFINITIVE LOH AT 19q. PLEASE REFER TO SEPARATELY DETAILED MOLECULAR DIAGNOSTIC REPORT.

[REDACTED]

*Electronic signature

Clinical History:
TUMOR

GROSS DESCRIPTION

(Continued on next page.)

ICD-O-3

Astrocytoma, grade II 9400/3

Site: ^{CDC} Brain, supratentorial NOS C71.1
^{path} Brain, temporal lobe C71.2

9/26/10/14

[page 2 of 3]
Patient: [REDACTED]

Path# [REDACTED]

[REDACTED] # [REDACTED]

Page 2

=====
PART #1: FS: BRAIN TUMOR #1

Resident Pathologist: [REDACTED]

FROZEN SECTION DIAGNOSIS:

Staff Pathologist: [REDACTED]

Brain tumor #1: Infiltrating glioma - grade deferred.

[REDACTED]
The specimen is received in saline labeled with the patient's name [REDACTED] and designated 'Brain tumor #1.' It consists of multiple soft pink-red fragments of tissue measuring 3.5 x 1.2 x 0.4 cm in aggregate. Touch preps are performed and the specimen is entirely submitted.

SUMMARY OF SECTIONS

1 - FSC - 3
1 - A - 2
2 - TOTAL - 5

PART #2: BRAIN TUMOR

Resident Pathologist: [REDACTED]
[REDACTED]

The specimen is received in saline, labeled with the patient's name, [REDACTED] and designated 'brain tumor.' The specimen consists of multiple, soft, white-pink, gelatinous fragments of tissue measuring 5.0 x 2.8 x 0.3 cm in aggregate. The specimen is entirely submitted.

SUMMARY OF SECTIONS

2 - A,B - MULTIPLE
2 - TOTAL - M

(Continued on next page.)

[page 3 of 3]
Patient: [REDACTED]

Path# [REDACTED]

[REDACTED] # [REDACTED]

Page 3

PART #3: TEMPORAL LOBE

Resident Pathologist: [REDACTED]

The specimen is received in saline, labeled with the patient's name, [REDACTED] and designated 'temporal lobe.' The specimen consists of two, soft, pink-white fragments of tissue measuring 0.8 x 0.6 x 0.2 cm in aggregate. The specimen is entirely submitted.

SUMMARY OF SECTIONS

- 1 - A - 2
- 1 - TOTAL - 2

(End of Report)

printed

Diagnostic Discrepancy		☒
HPV Discrepancy		☒
For Malignancy History		☒
Case is (circled)		

Source: NCI Genomic Data Commons file f23d6b4a-8b8a-4ec3-8666-becf8aca66ef (TCGA-WY-A85B.3BB27604-CFD2-4C1D-A53A-BB6EFA5F1D67.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).